Gene-level copy-number profile of tumor specimen C3N-03235-03 from CPTAC case C3N-03235, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 53.9 years (19,697 days).
Specimen C3N-03235-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f743a1b7-bbff-4fdd-aa2f-1ab4b1f0043e.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03235-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,229 have no estimate.
https://portal.gdc.cancer.gov/files/0e5145b2-d42f-4886-9ee3-b5c05577d0ee

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 30; copy number 2: 252; copy number 3: 2,197; copy number 4: 28,578; copy number 5: 17,361; copy number 6: 6,414; copy number 7: 3,102; copy number 8: 62; copy number 9: 218; copy number 10: 31; copy number 11: 44; copy number 12: 20; copy number 13: 68; copy number 15: 9; copy number 16: 8.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 359 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:150,321,479–150,353,233, 1 gene, copy number 10: PRPF3.
- chr1:154,974,653–155,087,538, 12 genes, copy number 9: CKS1B, MIR4258, FLAD1, LENEP, ZBTB7B, DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3.
- chr1:203,954,640–204,041,265, 2 genes, copy number 9: CBX1P3, LINC00303.
- chr1:246,509,038–246,839,611, 15 genes, copy number 9 (within-gene range 7–9): AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341.
- chr2:171,587,093–172,109,982, 9 genes, copy number 9: RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1, METAP1D, DLX1, DLX2, DLX2-DT.
- chr8:15,325,296–17,800,917, 34 genes, copy number 10–12: AC103851.1, TUSC3, AC100850.1, PPM1AP1, AC018437.3, AC018437.1, AC018437.2, MSR1, CCT3P1, MRPL49P2, AC011586.2, AC011586.1, RN7SL474P, FGF20, MICU3, AC079193.2, AC079193.1, ZDHHC2, CNOT7, VPS37A, MTMR7, ADAM24P, SLC7A2, AP006248.2, AP006248.4, SLC7A2-IT1, AP006248.3, PDGFRL, AP006248.1, AP006248.5, MTUS1, MIR548V, AC124069.1, RNA5SP256.
- chr8:38,269,704–38,382,272, 1 gene, copy number 16 (within-gene range 3–16): NSD3.
- chr8:38,335,981–42,555,195, 88 genes, copy number 9–16 (broad region; genes not listed).
- chr8:123,588,759–123,667,248, 2 genes, copy number 10 (within-gene range 7–10): RN7SKP155, AC135166.1.
- chr8:127,578,473–127,742,951, 3 genes, copy number 11: AC104370.1, CASC11, MYC.
- chr9:4,386,410–5,470,566, 40 genes, copy number 11: RNU6-694P, SLC1A1, SPATA6L, AL136231.1, PLPP6, CDC37L1-DT, CDC37L1, AK3, AL353151.2, ECM1P1, AL353151.1, RCL1, KLF4P1, MIR101-2, AL158147.1, HNRNPA1P41, JAK2, CSNK1G2P1, PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1, INSL4, RLN2, HMGN2P31, RLN1, AL135786.2, AL135786.1, PLGRKT, RNF152P1, CD274.
- chr9:5,584,490–5,588,994, 1 gene, copy number 11: AL162253.1.
- chr10:3,065,424–3,502,915, 9 genes, copy number 10: AL731533.2, PFKP, AL451164.2, PITRM1, PITRM1-AS1, AL451164.1, LINC02668, AL139280.1, LINC02669.
- chr10:3,748,966–8,973,468, 107 genes, copy number 9–10 (broad region; genes not listed).
- chr11:47,331,406–48,307,152, 35 genes, copy number 9: MYBPC3, SPI1, AC090559.1, MIR4487, SLC39A13, PSMC3, RAPSN, CELF1, AC090559.2, RN7SL652P, NDUFS3, PTPMT1, KBTBD4, RNU5E-10P, KF459542.1, FAM180B, C1QTNF4, MTCH2, AGBL2, FNBP4, Y_RNA, NUP160, AC021443.1, RNA5SP340, Y_RNA, YPEL5P2, AC023232.1, PTPRJ, PTPRJ-AS1, MIR3161, OR4B1, OR4B2P, OR4X2, OR4X1, OR4S1.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
